Gene-level copy-number profile of tumor specimen ALCH-AESG-TTP1-A from ALCHEMIST case ALCH-AESG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.5 years (23,566 days).
Specimen ALCH-AESG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8e5f66df-641d-4fd9-b278-e6677e707e35.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AESG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/3a0e78f5-2850-414a-ab29-df61248aa646

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 88; copy number 1: 2,993; copy number 2: 28,090; copy number 3: 18,391; copy number 4: 6,979; copy number 5: 1,022; copy number 6: 215; copy number 7: 369; copy number 8: 15; copy number 9: 33; copy number 10: 403; copy number 11: 205; copy number 12: 10; copy number 13: 26; copy number 14: 19; copy number 15: 1; copy number 17: 4; copy number 18: 19; copy number 19: 8; copy number 20: 15; copy number 21: 3.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,393,555–6,520,074, 7 genes (within-gene range 0–2): AL031848.2, HES2, ESPN, MIR4252, AL031848.1, TNFRSF25, PLEKHG5.
- chr2:232,343,116–232,351,309, 2 genes (within-gene range 0–2): NRBF2P6, ECEL1P3.
- chr2:232,479,827–232,525,716, 2 genes: ECEL1, PRSS56.
- chr3:75,384,059–75,580,199, 10 genes: AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15.
- chr6:42,915,989–43,036,500, 13 genes: PTCRA, AL035587.2, CNPY3, AL035587.1, RPL24P4, GNMT, PEX6, PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P.
- chr7:74,906,673–75,031,528, 2 genes (within-gene range 0–3): SPDYE12P, CASTOR2.
- chr9:21,966,929–22,128,103, 8 genes (within-gene range 0–2): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr14:103,550,345–103,562,831, 3 genes (within-gene range 0–2): RNU7-160P, AL139300.2, BAG5.
- chr14:103,567,405–103,567,545, 1 gene (within-gene range 0–2): RNU4-68P.
- chr16:28,474,111–28,512,051, 3 genes (within-gene range 0–2): CLN3, APOBR, IL27.
- chr16:67,723,070–68,000,586, 18 genes (within-gene range 0–2): RANBP10, AC010530.1, TSNAXIP1, CENPT, THAP11, NUTF2, AC040162.2, EDC4, AC040162.3, NRN1L, PSKH1, CTRL, AC040162.1, PSMB10, LCAT, SLC12A4, DPEP3, DPEP2.
- chr17:1,934,677–2,025,334, 2 genes (within-gene range 0–1): RTN4RL1, AC099684.2.
- chr21:45,405,165–45,513,720, 4 genes (within-gene range 0–2): COL18A1, COL18A1-AS2, COL18A1-AS1, MIR6815.
- chr22:30,368,811–30,421,771, 1 gene (within-gene range 0–3): RNF215.
- chr22:46,112,749–46,113,768, 3 genes (within-gene range 0–3): MIRLET7A3, MIR4763, MIRLET7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,367 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:178,090,677–189,133,292, 195 genes, copy number 5 (broad region; genes not listed).
- chr2:57,048,350–71,435,069, 280 genes, copy number 5 (broad region; genes not listed).
- chr2:172,137,345–177,559,299, 121 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr2:177,603,089–178,108,339, 5 genes, copy number 6 (within-gene range 2–6): AC073834.1, TTC30A, PDE11A, PDE11A, PDE11A-AS1.
- chr3:86,816,740–88,319,022, 20 genes, copy number 7: AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1.
- chr3:108,822,770–118,810,836, 139 genes, copy number 6 (broad region; genes not listed).
- chr3:120,512,850–120,513,188, 1 gene, copy number 19: AC126182.2.
- chr3:123,490,820–132,539,032, 215 genes, copy number 7 (broad region; genes not listed).
- chr3:135,925,891–136,337,896, 9 genes, copy number 20 (within-gene range 4–20): AC092989.1, NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2, MSL2, TDGF1P6, AC092991.1, PCCB.
- chr3:141,051,347–141,471,902, 10 genes, copy number 12–19: SPSB4, AC108727.2, PXYLP1, AC022215.2, AC022215.1, AC117383.1, AC117383.2, ZBTB38, AC010184.1, KRT18P35.
- chr3:142,306,607–143,177,617, 26 genes, copy number 13: XRN1, RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143, PLS1, PLS1-AS1, RN7SKP25, AC072028.1, TRPC1, RNU7-47P, PCOLCE2, AC021074.1, AC021074.3, PAQR9, AC021074.2, PAQR9-AS1, U2SURP, AC026304.1, AC018450.2, CHST2, AC018450.1, PBX2P1.
- chr3:163,109,152–163,361,563, 1 gene, copy number 5 (within-gene range 4–5): LINC01192.
- chr3:163,455,568–183,888,449, 292 genes, copy number 5–21 (broad region; genes not listed).
- chr3:187,721,377–198,123,232, 222 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr5:165,349,030–166,926,370, 8 genes, copy number 5: AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947.
- chr5:176,238,367–180,839,742, 165 genes, copy number 5 (broad region; genes not listed).
- chr7:74,650,231–74,789,376, 4 genes, copy number 6–15: GTF2I, AC211433.1, PHBP15, NCF1.
- chr7:132,648,794–138,701,362, 88 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:37,762,595–41,440,419, 81 genes, copy number 5–9 (broad region; genes not listed).
- chr8:69,424,849–69,860,540, 10 genes, copy number 17–20 (within-gene range 17–34): LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2.
- chr8:73,420,369–73,747,708, 1 gene, copy number 11 (within-gene range 2–11): STAU2.
- chr8:73,590,574–73,878,854, 4 genes, copy number 11 (within-gene range 2–11): AC100784.1, VENTXP6, AC027018.1, AC022826.2.
- chr8:91,542,924–91,907,619, 1 gene, copy number 10 (within-gene range 2–10): AC103409.1.
- chr8:91,909,738–92,103,286, 4 genes, copy number 10: PRR13P7, MRPS16P1, RUNX1T1, AF181450.1.
- chr8:101,686,542–102,124,907, 1 gene, copy number 10 (within-gene range 2–10): NCALD.
- chr8:101,847,256–102,688,906, 19 genes, copy number 10: AP001329.1, PDCL3P2, MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1, AP002981.1, RNU6ATAC8P, HSPE1P14, RPS12P15, AP002852.1, RNU6-1224P, ODF1, POU5F1P2, KLF10, ADI1P2.
- chr8:126,552,443–127,742,951, 15 genes, copy number 10: LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC.
- chr9:5,357,971–7,961,224, 44 genes, copy number 5: PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1, GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1, KDM4C, PRELID3BP11, SNRPEP2, ACTG1P14, AL513412.1, RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1.
- chr9:24,542,952–24,592,104, 2 genes, copy number 5: IZUMO3, AL353811.1.
- chr9:39,016,969–39,810,097, 20 genes, copy number 5: VN2R3P, CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1.
- chr10:56,595,963–59,960,913, 29 genes, copy number 5: AC025039.1, MIR3924, AL731534.1, AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1, AC016396.1, AC016396.2, UBE2D1, TFAM, BICC1, FAM133CP, RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553.
- chr10:60,734,342–61,001,440, 4 genes, copy number 6: ANK3-DT, CDK1, RHOBTB1, RNU2-72P.
- chr11:2,944,431–2,992,377, 3 genes, copy number 5: NAP1L4, SNORA54, AC131971.1.
- chr11:48,880,111–49,810,419, 25 genes, copy number 7–8: AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP, AC027369.2, TRIM51GP, TRIM53CP, AC027369.1, TRIM49B, TRIM64C, AC084851.3, AC084851.1, UBTFL7, AC084851.2, AC118273.1, AC118273.2, TRIM77BP, UBTFL9, FOLH1, AC118942.1, TYRL, CBX3P8, AC135977.1, AC136759.1.
- chr11:66,070,272–66,977,004, 56 genes, copy number 5: PACS1, AP000759.1, KLC2, AP001107.4, AP001107.8, AP001107.7, RAB1B, AP001107.1, AP001107.2, CNIH2, YIF1A, TMEM151A, AP001107.3, CD248, RIN1, AP001107.6, BRMS1, B4GAT1, AP001107.9, SLC29A2, Metazoa_SRP, BRD9P1, RNU1-84P, AP001107.5, NPAS4, AP002748.1, MRPL11, AP002748.3, PELI3, AP002748.4, DPP3, AP002748.5, BBS1, AP002748.6, ZDHHC24, ACTN3, AP002748.2, CTSF, CCDC87, CCS, RNU4-39P, RBM14, RBM14-RBM4, RBM4, RBM4B, SPTBN2, RN7SL12P, C11orf80, C1QBPP2, FTLP6, RCE1, PC, LRFN4, RNU7-23P, MIR3163, C11orf86.
- chr11:69,012,283–71,252,577, 52 genes, copy number 8–18 (within-gene range 2–18): MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr16:28,751,787–28,777,534, 2 genes, copy number 5–6: NPIPB9, AC145285.7.
- chr19:33,621,953–36,777,078, 171 genes, copy number 7–11 (broad region; genes not listed).
- chr21:43,414,483–43,479,534, 4 genes, copy number 7–18 (within-gene range 7–31): SIK1, LINC00319, LINC00313, AP001048.1.
- chr22:23,894,383–24,008,258, 17 genes, copy number 5 (within-gene range 3–5): MIF, MIF-AS1, AP000350.6, AP000350.2, AP000350.1, AP000350.3, GSTT2B, AC253536.2, DDTL, AC253536.6, DDT, AC253536.7, AC253536.1, AC253536.5, GSTT2, GSTT4, AC253536.4.

Autosomal genes at a single copy (total copy number 1): 1,950. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
